Somatic mutation profile of tumor specimen 0DVZ1H from CCDI case PBCNKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.1 years (5,877 days).
Specimen 0DVZ1H: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e98bf62-df0b-49f2-aad1-9699dc8fe750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c8888d8-efe2-4998-b751-6231f75e4728

The open-access MAF lists 45 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 12, Intron 5, Nonsense Mutation 3, Splice Region 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPP1 | c.2383C>T p.R795* (on ENST00000676605; = p.R754* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 36/214 reads (17%) | catalogued as rs771203308, CM140090, COSV51584477; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs371980049; called by muse, mutect2, varscan2
- EEF2 | c.615C>A p.I205= | Splice Region (SNP) | VAF 107/407 reads (26%) | catalogued as rs375130935, COSV58579656; called by muse, mutect2, varscan2
- EGLN2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 96/346 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs534813597, COSV99053253; called by muse, mutect2, varscan2
- LCNL1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs756026829, COSV56401055; called by muse, mutect2, varscan2
- OR8K5 | c.870C>A p.Y290* | Nonsense Mutation (SNP) | VAF 24/360 reads (7%) | catalogued as COSV57890305, COSV57891867; called by muse, mutect2
- RIMS2 | c.961G>A p.E321K (on ENST00000666250 / NM_001348490.2; = p.E129K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV51660195; called by muse, mutect2, varscan2
- STK24 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753779424; called by muse, mutect2, varscan2
- ADGRB3 | c.3436G>T p.V1146F | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- APOL6 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 144/516 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CALCOCO2 | c.-8C>G | Splice Region (SNP) | VAF 172/230 reads (75%) | called by muse, mutect2, varscan2
- CATSPERD | c.1290C>A p.S430R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GPR89B | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by mutect2, varscan2
- MAMDC4 | c.1544_1547dup p.S517Cfs*30 | Frame Shift Ins (INS) | VAF 91/189 reads (48%) | called by mutect2, pindel, varscan2
- MBP | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 250/428 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MRC2 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 67/442 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 168/410 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR3A3 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 113/154 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- OSBP2 | c.1880A>C p.H627P | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP2CB | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RFC2 | c.589C>G p.Q197E (on ENST00000055077 / NM_181471.3; = p.Q163E on NM_002914.4) | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SDHA | c.1705C>A p.Q569K | Missense Mutation (SNP) | VAF 127/308 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TCEA1 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 69/339 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TUFM | c.520-1G>T p.X174_splice | Splice Site (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- ZNF407 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 132/403 reads (33%) | called by muse, mutect2, varscan2
- ABCA3 | c.2889C>T p.Y963= | Silent (SNP) | VAF 98/214 reads (46%) | catalogued as rs773144605; called by muse, mutect2, varscan2
- ATP8A1 | c.1323C>A p.G441= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- FBXW11 | c.816T>C p.C272= | Silent (SNP) | VAF 58/152 reads (38%) | catalogued as COSV51606280; called by muse, mutect2, varscan2
- FLG | c.5670T>G p.S1890= | Silent (SNP) | VAF 98/247 reads (40%) | called by muse, mutect2, varscan2
- IZUMO2 | c.330G>A p.L110= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- LZTS1 | c.654C>A p.V218= | Silent (SNP) | VAF 100/376 reads (27%) | called by muse, varscan2
- PIGK | c.955T>C p.L319= | Silent (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- RIMS2 | c.267G>A p.A89= | Silent (SNP) | VAF 84/342 reads (25%) | catalogued as rs780523576; called by muse, mutect2, varscan2
- SPG7 | c.558G>T p.V186= | Silent (SNP) | VAF 100/250 reads (40%) | called by muse, mutect2, varscan2
- TMEM185A | c.270C>A p.I90= | Silent (SNP) | VAF 164/176 reads (93%) | catalogued as COSV57560291; called by muse, mutect2, varscan2
- TMEM209 | c.942C>T p.A314= | Silent (SNP) | VAF 67/270 reads (25%) | catalogued as rs778131899, COSV61022354; called by muse, mutect2, varscan2
- TTN | c.77229G>A p.A25743= (on ENST00000591111; = p.A18319= on NM_003319.4) | Silent (SNP) | VAF 118/301 reads (39%) | catalogued as rs771905375, COSV60135774; ClinVar: likely benign; called by muse, mutect2, varscan2
- BBS1 | c.518+56G>A | Intron (SNP) | VAF 33/243 reads (14%) | catalogued as rs369612079; called by muse, mutect2, varscan2
- INPPL1 | c.1713-43C>A | Intron (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- IQCM | c.*32A>T | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- PSMD11 | c.193+75G>A | Intron (SNP) | VAF 47/54 reads (87%) | called by muse, mutect2, varscan2
- RFC4 | c.882+32A>G | Intron (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- TIGD5 | c.-2C>T | 5'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2
- TPCN1 | c.1707-73G>A | Intron (SNP) | VAF 8/31 reads (26%) | catalogued as rs571165819; called by muse, mutect2, varscan2
- TTC6 | chr14:37790743 C>G | 5'Flank (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
